Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A1CT, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A1CT-01A (Primary Tumor).

[page 1 of 3]
100-0-3
Carcinoma, Papillary, Thyroid 8260/3
Site Code: Thyroid, NOS C73.9 1/9/11
lw

Surgical Pathology Consultation Report

Patient Name:

MRN:

DOB:

Gender: M

HCN:

Ordering MD:

Copy To:

Service:

Visit #:

Location:

Facility:

Accession #:

Collected:

Received:

Reported:

Specimen(s) Received

1. Nck: right neck content stitch marks apex
2. Nck: Posterior triangle right neck
3. Neck: Posterior apex Right neck
4. Thyroid: total thyroidectomy stitch marks upper pole fresh for tumor banking
5. Parathyroid: Right upper parathyroid

Diagnosis

1. Metastatic papillary thyroid carcinoma with extranodal extension: Lymph node, 1 of 4 (right neck) dissection specimen
2. No pathological diagnosis: Lymph nodes, 9 (right neck posterior triangle) dissection specimen.
3. No pathological diagnosis: Lymph nodes, 9, (right neck posterior apex), dissection specimen
4. Papillary carcinoma, 1.5 cm, classic variant, right, with positive resection margin: Thyroid
No pathological diagnosis: Parathyroid, left
-Total thyroidectomy specimen
5. No pathological diagnosis: Parathyroid (right upper) biopsy

Synoptic Data

Procedure:

Received:

Specimen Integrity:

Specimen Size:

Total thyroidectomy with right neck dissection

Fresh

Intact

Right lobe:

3.2 cm

2.4 cm

1.4 cm

Left lobe:

2.9 cm

2.0 cm

1.0 cm

Isthmus +/- pyramidal lobe:

2.5 cm

1.5 cm

0.6 cm

Reviewed Initials	RM	3/1/11

[page 2 of 3]
Surgical Pathology Consultation Report

Right neck dissection:
10 cm
3.5 cm
2.9 cm
Specimen Weight: 11.1 g
Tumor Focality: Unifocal
----- DOMINANT TUMOR -----
Tumor Laterality: Right lobe
Tumor Size: Greatest dimension: 1.5cm
Additional dimension: 1.5 cm
Additional dimension: 1.5 cm
Histologic Type: Papillary carcinoma, classical (usual)
Classical (papillary) architecture
Classical cytomorphology
Histologic Grade: Not applicable
Margins: Margin(s) involved by carcinoma
Tumor Capsule: Totally encapsulated
Tumor Capsular Invasion: Present, extent widely invasive
Lymph-Vascular Invasion: Indeterminate
Perineural Invasion: Not identified
Extrathyroidal Extension: Not identified
TNM Descriptors: Not applicable
Primary Tumor (pT): pT1b: Tumor more than 1 cm but not more than 2 cm in greatest dimension, limited to the thyroid
Regional Lymph Nodes (pN): pN1b: Metastases to unilateral, bilateral or contralateral cervical or superior mediastinal lymph nodes
Number of regional lymph nodes examined: 22
Number of regional lymph nodes involved: 1
Lymph Node, Extranodal Extension Present
Distant Metastasis (pM): Not applicable
Additional Pathologic Findings: Adenomatoid nodule(s) or Nodular follicular disease
Parathyroid gland(s), within normal limits
Parathyroid gland(s), other: left

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Comment

4. Many areas are highly suspicious for vascular invasion, however unequivocal evidence is not found.

Electronically verified by:

Clinical History

papillary ca thyroid

Gross Description

1. The specimen labeled with the patient's name and as "right neck contents" consists of a piece of fibroadipose tissue that measures 10.2 x 2.5 x 1.5 cm. One suture marks the apex. On sectioning, the specimen contains one well defined lesion measuring 2.6 x 2.0 x 1.8 cm close to the apex, 2 lymph nodes that measure 1.0 x 0.4 x 0.4 cm each, and one piece of muscle measuring 2.0 x 1.5 x 1.5 cm. Representative sections are submitted as follows:

1A-D large lesion transected and submitted in toto
1E two lymph nodes

[page 3 of 3]
Surgical Pathology Consultation Report

2. The specimen labeled with the patient's name and as "posterior triangle right neck" consists of a piece of fibroadipose tissue that measures 5.0 x 3.5 x 0.8 cm and contains multiple lymph nodes that range from 0.3 to 0.5 cm. Representative sections are submitted as follows:
2A, 2B multiple lymph nodes
3. The specimen labeled with the patient's name and as "posterior apex right neck" consists of a piece of fibroadipose tissue that measures 3.3 x 1.7 x 0.6 cm and contains multiple possible lymph nodes that range from 0.2 to 0.3 cm. Tissue is submitted in total as follows:
3A multiple possible lymph nodes
3B, C remainder of fibrofatty tissue submitted in toto
4. The specimen labeled with the patient's name and as "total thyroidectomy" consists of a thyroid gland that is oriented with a suture and weighs 11.1 g. The right lobe measures 3.2 cm SI x 2.4 cm ML x 1.4 cm AP, the left lobe measures 2.9 cm SI x 2.0 cm ML x 1.0 cm AP and the isthmus measures 2.5 cm SI x 1.5 cm ML x 0.6 cm AP. The external surfaces have fibrous adhesions. No parathyroid glands or lymph nodes are identified grossly. The external surface is painted with silver nitrate. The upper pole of the right lobe contains one delineated nodule that measures 1.5 cm SI x 1.5 cm ML x 1.5 cm AP. The remainder of the thyroid tissue is unremarkable. Sections of the nodule and left lobe normal tissue are stored frozen. The remainder of the specimen is submitted as follows:
4A-F right lobe, superior to inferior
4G, H isthmus
4I-L left lobe, superior to inferior
5. The specimen labeled with the patient's name and as "parathyroid: Right upper parathyroid" consists of a very small piece of tan tissue that measures less than 0.1 cm. It is frozen for intraoperative consultation.
5A frozen section block resubmitted

Quick Section Diagnosis

5. Right upper parathyroid: Parathyroid tissue,

Source: NCI Genomic Data Commons file 7ef53c3f-e501-40d3-b035-9b3f1b3fa947 (TCGA-EM-A1CT.A4AF37AD-CD79-4B94-92F8-005093DF0CA3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).